Somatic mutation profile of tumor specimen MBCProject_0054_T1B_2_WES (aliquot MBCProject_0054_T1B_2_WES_1) from CMI case MBCProject_0054, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 47.0 years (17,178 days).
Specimen MBCProject_0054_T1B_2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f1fc77c-8d38-412b-a236-b917bf533cce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0054_SALIVA (Saliva), aliquot MBCProject_0054_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6170dc3-62e8-42e7-9395-e4c138b25ab6

The open-access MAF lists 90 somatic variants for this specimen: 20 protein-altering or splice-affecting, 57 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 57, Missense Mutation 15, Intron 8, RNA 3, Splice Site 2, In Frame Del 2, 3'UTR 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC171 | c.3380A>G p.H1127R | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs1193543684; called by muse, varscan2
- COL7A1 | c.1999G>A p.V667I | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs768493397; called by mutect2, varscan2
- DSCAML1 | c.44_49del p.Q15_S17delinsR | In Frame Del (DEL) | VAF 6/62 reads (10%) | catalogued as COSV58403160; called by mutect2, varscan2
- EBF3 | c.1499G>A p.S500N (on ENST00000355311 / NM_001375392.1; = p.S491N on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV62471376, COSV62475439; called by muse, varscan2
- GATA3 | c.987dup p.R330Efs*22 | Frame Shift Ins (INS) | VAF 64/334 reads (19%) | catalogued as COSV99062092; called by mutect2, pindel, varscan2
- H2AX | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as rs778838502, COSV53828020; called by mutect2, varscan2
- HECTD1 | c.4199G>C p.G1400A | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV67944875, COSV67945622; called by muse, varscan2
- KMT2A | c.8275G>A p.E2759K | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs782694778, COSV100629452; called by muse, mutect2, varscan2
- MIEF1 | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV57480184; called by muse, mutect2, varscan2
- MYL10 | c.78+2T>C p.X26_splice | Splice Site (SNP) | VAF 6/58 reads (10%) | catalogued as rs1364564511, COSV56208945; called by muse, mutect2
- NEB | c.8528T>A p.F2843Y | Missense Mutation (SNP) | VAF 26/353 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as COSV50807851; called by muse, mutect2
- NR1D1 | c.1739T>C p.L580S | Missense Mutation (SNP) | VAF 14/320 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV52840542; called by muse, mutect2
- PIGT | c.713T>C p.L238P | Missense Mutation (SNP) | VAF 37/266 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54129129; called by muse, mutect2, varscan2
- TIMELESS | c.3272T>C p.L1091P | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780149502; called by mutect2, varscan2
- UGT3A2 | c.449G>T p.C150F | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56934441; called by muse, mutect2, varscan2
- BCL3 | c.891+1G>C p.X297_splice | Splice Site (SNP) | VAF 11/116 reads (9%) | called by muse, mutect2, varscan2
- CDH5 | c.1956G>C p.E652D | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DDX5 | c.1115A>G p.H372R | Missense Mutation (SNP) | VAF 46/442 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MBD6 | c.2198_2200del p.P733del | In Frame Del (DEL) | VAF 6/40 reads (15%) | called by pindel, varscan2
- SLC25A12 | c.1736G>A p.G579E | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AHSA1 | c.183G>C p.V61= | Silent (SNP) | VAF 18/364 reads (5%) | called by muse, mutect2
- AMD1 | c.261G>A p.L87= | Silent (SNP) | VAF 12/178 reads (7%) | catalogued as rs1284561715, COSV64386891; called by muse, mutect2
- ASTN1 | c.1368A>G p.G456= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV56072160; called by muse, varscan2
- ATXN2L | c.3150A>G p.S1050= | Silent (SNP) | VAF 9/145 reads (6%) | catalogued as rs1296934706, COSV57364680; called by muse, mutect2
- CABIN1 | c.4011C>T p.L1337= | Silent (SNP) | VAF 14/138 reads (10%) | called by muse, mutect2
- CACNA1H | c.4599G>C p.L1533= | Silent (SNP) | VAF 9/96 reads (9%) | called by muse, varscan2
- CAPZA1 | c.828C>T p.S276= | Silent (SNP) | VAF 13/138 reads (9%) | called by muse, mutect2, varscan2
- CDK5R2 | c.930G>A p.R310= | Silent (SNP) | VAF 22/390 reads (6%) | catalogued as rs1192336701; called by muse, mutect2
- CHD6 | c.2547T>C p.D849= | Silent (SNP) | VAF 16/302 reads (5%) | called by muse, mutect2
- CHSY3 | c.750C>T p.Y250= | Silent (SNP) | VAF 6/52 reads (12%) | called by muse, varscan2
- CLK3 | c.870T>C p.G290= (on ENST00000395066 / NM_001130028.1; = p.G142= on NM_003992.4) | Silent (SNP) | VAF 8/116 reads (7%) | catalogued as rs1323690218, COSV61411668; called by muse, mutect2
- CYP26C1 | c.315C>T p.I105= | Silent (SNP) | VAF 22/166 reads (13%) | catalogued as rs753858637; called by muse, varscan2
- DSCAM | c.2799G>A p.Q933= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV68020046; called by muse, mutect2, varscan2
- EBF3 | c.687A>T p.S229= | Silent (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- FAM135A | c.1171T>C p.L391= (on ENST00000370479 / NM_001351599.1; = p.L374= on NM_020819.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 14/216 reads (6%) | catalogued as COSV52053068; called by muse, mutect2
- FOXE1 | c.189C>T p.A63= | Silent (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- FOXQ1 | c.471C>G p.R157= | Silent (SNP) | VAF 6/81 reads (7%) | called by muse, mutect2
- FRMPD3 | c.5262A>G p.Q1754= | Silent (SNP) | VAF 68/288 reads (24%) | catalogued as rs1201202558; called by muse, varscan2
- GCSAML | c.288A>C p.T96= | Silent (SNP) | VAF 21/143 reads (15%) | called by muse, mutect2, varscan2
- GNG5 | c.156A>G p.V52= | Silent (SNP) | VAF 18/178 reads (10%) | catalogued as COSV55364658; called by muse, mutect2
- HERC4 | c.1731T>C p.G577= | Silent (SNP) | VAF 12/168 reads (7%) | catalogued as COSV53268348; called by muse, mutect2
- HIC1 | c.246C>A p.L82= (on ENST00000322941 / NM_001098202.1; = p.L63= on NM_006497.4) | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV53964464; called by muse, mutect2
- ING4 | c.591C>A p.T197= (on ENST00000396807 / NM_001127582.2; = p.T196= on NM_016162.4) | Silent (SNP) | VAF 6/65 reads (9%) | called by muse, mutect2, varscan2
- JADE1 | c.1455A>G p.L485= | Silent (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- LDB1 | c.1098A>G p.A366= (on ENST00000425280 / NM_001321612.2; = p.A332= on NM_003893.5) | Silent (SNP) | VAF 24/450 reads (5%) | catalogued as COSV63288811; called by muse, mutect2
- LHFPL3 | c.111C>T p.N37= | Silent (SNP) | VAF 21/199 reads (11%) | catalogued as COSV67804741; called by muse, varscan2
- LHFPL3 | c.141A>C p.I47= | Silent (SNP) | VAF 21/155 reads (14%) | catalogued as COSV67804752; called by muse, varscan2
- LHFPL3 | c.234C>T p.G78= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV67804761; called by muse, varscan2
- LHFPL3 | c.291T>C p.F97= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV67804768; called by muse, varscan2
- MAGI2 | c.1134T>C p.N378= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as COSV62698020; called by muse, mutect2
- MAP2K4 | c.378A>G p.Q126= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV62254854; called by muse, mutect2, varscan2
- MBD6 | c.2205C>T p.L735= | Silent (SNP) | VAF 8/32 reads (25%) | called by muse, varscan2
- MED1 | c.1956T>C p.N652= | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as COSV56122107; called by muse, mutect2, varscan2
- NEB | c.8529C>T p.F2843= | Silent (SNP) | VAF 26/352 reads (7%) | catalogued as COSV50807815, COSV51443776; called by muse, mutect2
- NOVA1 | c.1380A>G p.K460= | Silent (SNP) | VAF 20/196 reads (10%) | catalogued as COSV57471603; called by muse, varscan2
- NR2F2 | c.381T>C p.H127= | Silent (SNP) | VAF 12/224 reads (5%) | catalogued as COSV67682996; called by muse, mutect2
- NR4A2 | c.153C>T p.I51= | Silent (SNP) | VAF 18/405 reads (4%) | catalogued as COSV59892427; called by muse, mutect2
- NRXN3 | c.1629G>A p.P543= (on ENST00000557594 / NM_001272020.2; = p.P967= on NM_004796.6) | Silent (SNP) | VAF 19/183 reads (10%) | catalogued as rs1254494576, COSV55313998, COSV55324090; called by muse, varscan2
- NRXN3 | c.1798C>A p.R600= (on ENST00000557594 / NM_001272020.2; = p.R1024= on NM_004796.6) | Silent (SNP) | VAF 18/140 reads (13%) | catalogued as COSV55321428, COSV55332853; called by muse, varscan2
- PABPC1 | c.1410T>C p.S470= | Silent (SNP) | VAF 16/217 reads (7%) | called by muse, mutect2
- PGK1 | c.873G>A p.K291= | Silent (SNP) | VAF 12/146 reads (8%) | called by muse, mutect2
- PHOX2B | c.174T>G p.P58= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV56928118; called by muse, varscan2
- PI4KB | c.2310A>C p.R770= (on ENST00000368873 / NM_001369623.1; = p.R782= on NM_002651.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/67 reads (15%) | called by muse, mutect2, varscan2
- PKP4 | c.225A>G p.S75= | Silent (SNP) | VAF 10/119 reads (8%) | called by muse, mutect2, varscan2
- PPP1CC | c.571C>A p.R191= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as rs866672821, COSV58582427; called by muse, mutect2, varscan2
- QRICH1 | c.903T>A p.I301= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as COSV62614385; called by muse, varscan2
- RIMS1 | c.153A>G p.E51= | Silent (SNP) | VAF 10/88 reads (11%) | called by muse, varscan2
- SCN8A | c.3954T>C p.N1318= | Silent (SNP) | VAF 19/156 reads (12%) | called by muse, varscan2
- SETD1B | c.132T>C p.H44= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as COSV57354311; called by muse, mutect2
- SIX2 | c.129T>C p.L43= | Silent (SNP) | VAF 14/132 reads (11%) | catalogued as rs1432211155, COSV57389958; called by muse, varscan2
- SIX2 | c.93C>T p.G31= | Silent (SNP) | VAF 9/68 reads (13%) | called by muse, varscan2
- SLC6A9 | c.375C>T p.R125= (on ENST00000360584 / NM_201649.4; = p.R71= on NM_006934.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/147 reads (7%) | catalogued as COSV62209789; called by muse, mutect2
- STX6 | c.561C>G p.S187= | Silent (SNP) | VAF 13/164 reads (8%) | called by muse, mutect2
- TJP1 | c.132C>G p.P44= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs1476379784; called by muse, varscan2
- TRAPPC12 | c.2043C>G p.V681= | Silent (SNP) | VAF 12/98 reads (12%) | called by muse, varscan2
- UBE2QL1 | c.147C>A p.T49= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV67715394; called by muse, varscan2
- UNC79 | c.321C>T p.P107= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as rs1372490934, COSV56393927; called by muse, varscan2
- AGAP3 | c.1020+387C>A | Intron (SNP) | VAF 8/73 reads (11%) | called by muse, varscan2
- ARMH1 | c.921-15G>A | Intron (SNP) | VAF 10/108 reads (9%) | catalogued as rs1024159986; called by muse, mutect2, varscan2
- CASP2 | c.967+177G>A | Intron (SNP) | VAF 17/270 reads (6%) | catalogued as rs1287827257; called by muse, mutect2
- CCDC162P | n.6399C>T | RNA (SNP) | VAF 20/242 reads (8%) | catalogued as rs1347674714; called by muse, mutect2
- DOCK9 | c.4062-43T>G | Intron (SNP) | VAF 8/69 reads (12%) | called by muse, varscan2
- EDRF1 | c.2371+161A>G | Intron (SNP) | VAF 8/66 reads (12%) | catalogued as rs1299179669; called by mutect2, varscan2
- INTS10 | c.1977-2463A>G | Intron (SNP) | VAF 10/111 reads (9%) | called by muse, mutect2
- KCNC1 | chr11:17781660 T>C | 3'Flank (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- KHSRP | c.2127+12T>C | Intron (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- MIR212 | n.66C>T | RNA (SNP) | VAF 14/302 reads (5%) | called by muse, mutect2
- RBFOX3 | c.756-21T>C | Intron (SNP) | VAF 14/137 reads (10%) | called by muse, varscan2
- SUMO2P21 | n.72G>A | RNA (SNP) | VAF 26/168 reads (15%) | catalogued as rs1556648328; called by muse, mutect2
- ZNF827 | c.*3T>G | 3'UTR (SNP) | VAF 8/113 reads (7%) | catalogued as COSV65230716; called by muse, mutect2
